Somatic mutation profile of tumor specimen C3N-02594-01 (aliquot CPT0187640031) from CPTAC case C3N-02594, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 65.4 years (23,874 days).
Specimen C3N-02594-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc4f61c9-31d0-4d34-9891-c0f45c2aee76.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02594-31 (Blood Derived Normal), aliquot CPT0187700002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cabfa309-a006-44df-b06b-9dbf17a13072

The open-access MAF lists 58 somatic variants for this specimen: 40 protein-altering or splice-affecting, 10 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 10, Nonsense Mutation 3, Intron 3, 5'Flank 2, RNA 1, Frame Shift Ins 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 162/922 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913381, CM071585, CM973278, COSV58682998, COSV58690035, COSV58690777, COSV58726216; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 37/255 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAX | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 46/644 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52414939; called by muse, mutect2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 66/480 reads (14%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AASS | c.2728C>T p.R910* | Nonsense Mutation (SNP) | VAF 20/299 reads (7%) | catalogued as rs1463650183, COSV62791220; called by muse, mutect2
- ADCYAP1R1 | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.251); catalogued as rs374708368; called by muse, mutect2, varscan2
- AMER1 | c.2036G>A p.R679Q | Missense Mutation (SNP) | VAF 28/461 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs777453882, COSV57660865; called by muse, mutect2
- CABIN1 | c.5047G>A p.G1683R | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs529990301, COSV99572525; called by muse, mutect2
- COL3A1 | c.1282C>T p.R428* | Nonsense Mutation (SNP) | VAF 34/868 reads (4%) | catalogued as COSV58593877; called by muse, mutect2
- IGHV1-46 | c.329C>T p.T110M | Missense Mutation (SNP) | VAF 61/521 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.283); catalogued as rs781917710; called by muse, mutect2, varscan2
- IL4I1 | c.1520G>A p.R507Q | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs749043676; called by muse, mutect2, varscan2
- KCND1 | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 26/298 reads (9%) | SIFT tolerated, low confidence (0.61); PolyPhen possibly damaging (0.451); catalogued as rs1349206831, COSV54415823; called by muse, mutect2
- MIDEAS | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.098); catalogued as rs1048677076; called by muse, mutect2, varscan2
- OR13G1 | c.131T>C p.I44T | Missense Mutation (SNP) | VAF 33/332 reads (10%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs1172980016; called by muse, mutect2
- OR2T10 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 30/349 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.07); catalogued as rs772598617; called by muse, mutect2
- PDZD7 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 95/677 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766751821, COSV100931662; called by muse, mutect2, varscan2
- REEP4 | c.293G>T p.R98L | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs199643121; called by muse, mutect2
- RIMBP2 | c.1585G>A p.V529M | Missense Mutation (SNP) | VAF 42/247 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs745374088, COSV55474609; called by muse, varscan2
- SMAD4 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555685186, COSV61685472; ClinVar: uncertain significance; called by muse, mutect2
- SURF6 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 27/413 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1019883142; called by muse, mutect2
- TRPS1 | c.2347G>A p.E783K (on ENST00000220888 / NM_001330599.2; = p.E796K on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/599 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.026); catalogued as rs1322332596, COSV55233555, COSV55264988; called by muse, mutect2
- UNC80 | c.4982G>A p.R1661Q | Missense Mutation (SNP) | VAF 15/204 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1490619535; called by muse, mutect2
- XIRP2 | c.8954C>T p.S2985L (on ENST00000628543; = p.S3160L on NM_152381.6) | Missense Mutation (SNP) | VAF 26/294 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV54704762; called by muse, mutect2
- ADAMTS16 | c.3055T>A p.S1019T | Missense Mutation (SNP) | VAF 62/469 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- CACNA1D | c.2516T>C p.V839A (on ENST00000350061 / NM_001128840.3; = p.V859A on NM_000720.4) | Missense Mutation (SNP) | VAF 58/453 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DIP2A | c.3290C>G p.A1097G | Missense Mutation (SNP) | VAF 29/246 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- DISC1 | c.971A>T p.H324L | Missense Mutation (SNP) | VAF 65/471 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- FAM161B | c.1076A>C p.K359T (on ENST00000651776; = p.K296T on NM_152445.3) | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- IRS4 | c.248G>A p.G83D | Missense Mutation (SNP) | VAF 29/464 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ITPRIPL2 | c.1538C>A p.P513H | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.96); called by muse, mutect2
- NEB | c.5348T>C p.L1783P | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- NKPD1 | c.2207C>T p.A736V | Missense Mutation (SNP) | VAF 19/538 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- OGT | c.1062A>C p.L354F | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RUNX1T1 | c.1725_1726dup p.A576Gfs*25 (on ENST00000265814 / NM_001198628.1; = p.A549Gfs*25 on NM_004349.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 81/814 reads (10%) | called by mutect2, pindel, varscan2
- SMG1 | c.10283T>A p.L3428H | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TAF3 | c.2317G>A p.V773I | Missense Mutation (SNP) | VAF 30/640 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2
- TMEM156 | c.683T>G p.I228S | Missense Mutation (SNP) | VAF 14/306 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2
- TNRC18 | c.902G>A p.G301E | Missense Mutation (SNP) | VAF 27/251 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- WASHC2C | c.1855A>T p.S619C | Missense Mutation (SNP) | VAF 19/390 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF536 | c.2101G>A p.G701R | Missense Mutation (SNP) | VAF 34/244 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACSS2 | c.1287G>A p.R429= | Silent (SNP) | VAF 33/218 reads (15%) | catalogued as rs778138544; called by mutect2, varscan2
- ADAMTS10 | c.2772C>T p.D924= | Silent (SNP) | VAF 15/166 reads (9%) | catalogued as rs781947411, COSV54359057; called by muse, mutect2
- DLGAP2 | c.792C>T p.D264= | Silent (SNP) | VAF 37/356 reads (10%) | catalogued as rs754587007, COSV101421746, COSV70096341; called by muse, mutect2
- FAAH | c.285C>G p.A95= | Silent (SNP) | VAF 59/504 reads (12%) | catalogued as COSV54544040, COSV54544512; called by muse, mutect2, varscan2
- FANCB | c.2397G>A p.A799= | Silent (SNP) | VAF 23/188 reads (12%) | catalogued as rs746293753, COSV60761971; called by muse, mutect2, varscan2
- IRX4 | c.450G>A p.T150= | Silent (SNP) | VAF 16/258 reads (6%) | catalogued as rs200279409, COSV51471722; called by muse, mutect2
- ISLR2 | c.219C>T p.D73= | Silent (SNP) | VAF 14/248 reads (6%) | catalogued as COSV62301723; called by muse, mutect2
- MEIOC | c.735T>G p.S245= | Silent (SNP) | VAF 10/168 reads (6%) | called by muse, mutect2
- TENM3 | c.2448G>A p.P816= | Silent (SNP) | VAF 31/508 reads (6%) | catalogued as rs370217002; called by muse, mutect2
- ZSWIM8 | c.5370G>A p.A1790= (on ENST00000605216 / NM_001242487.2; = p.A1795= on NM_015037.3) | Silent (SNP) | VAF 28/269 reads (10%) | catalogued as rs371197279; called by muse, mutect2, varscan2
- BHLHE22 | chr8:64576466 G>A | 5'Flank (SNP) | VAF 38/202 reads (19%) | called by muse, mutect2, varscan2
- CHRNA4 | c.*1272G>A | 3'UTR (SNP) | VAF 4/28 reads (14%) | catalogued as rs1181117614; called by muse, mutect2
- GMPR2 | c.857+33T>C | Intron (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- HSP90AB3P | n.1914G>A | RNA (SNP) | VAF 26/520 reads (5%) | catalogued as rs766142087; called by muse, mutect2
- KRTAP22-1 | c.-14C>A | 5'UTR (SNP) | VAF 30/422 reads (7%) | called by muse, mutect2
- NT5C3A | c.139-2742C>T | Intron (SNP) | VAF 14/206 reads (7%) | catalogued as rs757525881; called by muse, mutect2
- RARG | c.1018+27T>C | Intron (SNP) | VAF 21/272 reads (8%) | catalogued as rs747123379; called by muse, mutect2
- SLC25A13 | chr7:96322121 G>T | 5'Flank (SNP) | VAF 20/168 reads (12%) | catalogued as rs1027911138; called by muse, varscan2
